Surgical pathology report (de-identified scan), TCGA case TCGA-CR-6472, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-6472-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

Accession Number: [REDACTED]

Final Report

DIAGNOSIS:

1) TONGUE, LEFT BASE/TONSIL, EXCISION: INVASIVE MODERATELY TO POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA.

Electronically signed by: [REDACTED]

CLINICAL DATA

Clinical Features/Dx: unspecified

Operator: [REDACTED]

Operation: unspecified

Operative Findings: unspecified

Operative Diagnosis: unspecified

Tissue Submitted: 1) left tongue base/tonsil

GROSS DESCRIPTION:

1) SOURCE: Left Tongue Base/ Tonsil

"Left tongue base/tonsil," is received fresh and consists of several fragments of opaque, tan to red polypoid mucosal tissue, measuring 2.1 x 0.9 x 0.2 cm in aggregate. The specimen is submitted for evaluation in its entirety.

Summary of sections: 1A, tongue base, m/1.

Dictated by [REDACTED]

Slides and report reviewed by Attending Pathologist.

SNOMED: T-53131,M-80703,

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file e72b3e40-47d0-4149-bb09-43f3f5f05336 (TCGA-CR-6472.D4C4D2A4-DD8F-4BE6-83EC-8F4F48B375C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).